Somatic mutation profile of tumor specimen TCGA-DJ-A3UW-01A (aliquot TCGA-DJ-A3UW-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 50.6 years (18,487 days).
Specimen TCGA-DJ-A3UW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df20c252-a23c-4577-989c-6f17a55dcfd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UW-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UW-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08cc374e-158f-4bdc-a787-2baa57afc0d6

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ITPR2 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs756094266, COSV67272811; called by muse, mutect2, varscan2
- RNPEPL1 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV54373285; called by muse, mutect2, varscan2
- DUOX1 | c.471G>A p.R157= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58484142; called by muse, mutect2, varscan2
- IQCN | c.3270C>T p.G1090= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs369557718; called by muse, mutect2, varscan2
